TCGA case TCGA-WK-A8XT — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Synovial-like Neoplasms; Primary site: Kidney; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/479d7a5a-63dc-412b-9075-920525334fe7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Dead; Days to death: 1,262 days (3.5 years).

Diagnoses (6)
1. Synovial sarcoma, spindle cell (the primary disease): ICD-O-3 morphology code: 9041/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 41.0 years (14,958 days); Year of diagnosis: 2008; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.8; Tumor length measurement: 3.2; Tumor width measurement: 2.7.
   Pathology details: Measurement type: Pathologic; Tumor burden: 3.2.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.1; Tumor width measurement: 3.
   Pathology details: Measurement type: Radiologic; Tumor burden: 3.1.
2. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Specified parts of peritoneum; Classification of tumor: Prior primary; Age at diagnosis: 31.9 years (11,639 days); Days to diagnosis: -3,319 days (-9.1 years).
3. Recurrence of diagnosis 1 (Synovial sarcoma, spindle cell), site: Other ill-defined sites. Age at diagnosis: 42.6 years (15,557 days); Days to diagnosis: 599 days (1.6 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Tumor burden: 2.9.
   Pathology details: Measurement type: Pathologic; Tumor burden: 2.8.
4. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Lung, NOS. Age at diagnosis: 43.2 years (15,787 days); Days to diagnosis: 829 days (2.3 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Bone, NOS. Age at diagnosis: 43.7 years (15,945 days); Days to diagnosis: 987 days (2.7 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Liver. Age at diagnosis: 43.7 years (15,945 days); Days to diagnosis: 987 days (2.7 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 599 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Other ill-defined sites; Days to recurrence: 599 days (1.6 years).
- Day 829 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 829 days (2.3 years).
- Day 987 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 987 days (2.7 years).
- Day 987 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 987 days (2.7 years).
- Days to follow up: 1,262 days (3.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 50.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-WK-A8XT-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Synovial Sarcoma - Monophasic; Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Synovial sarcoma: Synovial ss18ssx testing method: FISH for SS18 split.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Kidney.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 3.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Mesentery; Other malignancy histological type: desmoid fibromatosis.
- Other malignancy form, Surgery: Other malignancy surgery type: small bowel resection; Days from index date to other malignancy surgery: -3307.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,262 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,262 days; disease-free interval: event (new tumor event after initially disease-free), 599 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 599 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WK-A8XT-01A-11D-A37B-01): tumor purity 0.85, ploidy 1.93, whole-genome doublings 0.
